Surgical pathology report (de-identified scan), TCGA case TCGA-21-1070, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-1070-01A (Primary Tumor).

[page 1 of 4]
Clinical History/Diagnosis: LEFT LUNG CA, HX OF LEFT BREAST CA WITH LUMPECTOMY AND AXILLARY DISSECTION, CHEMO AND RADIATION

Specimen(s): 1 PORTION OF POSTERIOR 5TH RIB LEFT
2 PORTION OF POSTERIOR 4TH RIB LEFT
3 PORTION OF POSTERIOR 3RD RIB
4 LEVEL NINE LYMPH NODE
5 LEVEL FIVE LYMPH NODE LEFT
6 LEFT ELEVEN LYMPH NODE
7 LEFT UPPER LOBE OF LUNG WITH CHEST WALL
8 LEVEL 7 LYMPH NODE

GROSS DESCRIPTION: Received in eight parts.

SOURCE OF TISSUE: 1. Labeled #1 ""posterior left fifth rib"".

GROSS DESCRIPTION: Received fresh is a 1.0cm in greatest dimension, tan-pink fragment of rib which is bisected and entirely submitted in one block, following decalcification.

DESIGNATION OF SECTIONS: Block 1.

SUMMARY OF SECTIONS: Undesignated-2.

SOURCE OF TISSUE: 2. Labeled #2, ""portion of posterior left fourth rib"".

GROSS DESCRIPTION: Received fresh is a 1.5cm in greatest dimension tan-pink fragment of rib which is bisected and entirely submitted in one block, following decalcification.

DESIGNATION OF SECTIONS: Block 2.

SUMMARY OF SECTIONS: Undesignated-2.

SOURCE OF TISSUE: 3. Labeled #3, ""portion of posterior left third rib"".

GROSS DESCRIPTION: Received fresh is a 1.5cm in greatest dimension, tan-pink fragment of rib which is bisected and entirely submitted in one block,

[page 2 of 4]
following decalcification.

DESIGNATION OF SECTIONS: Block 3.

SUMMARY OF SECTIONS: Undesignated-2.

SOURCE OF TISSUE: 4. Labeled #4, ""level 9 lymph node"".

GROSS DESCRIPTION: Received fresh are several gray-black, anthracotic-stained lymph nodes with attached adipose tissue, 0.8cm in greatest dimension. They are submitted in toto in one block.

DESIGNATION OF SECTIONS: Block 4.

SUMMARY OF SECTIONS: Undesignated-2.

SOURCE OF TISSUE: 5. Labeled #5, ""left level 5 lymph node"".

FROZEN SECTION DIAGNOSIS: 5FS - NO TUMOR SEEN

GROSS DESCRIPTION: Received fresh for frozen section evaluation are two tan to gray-black, focally anthracotic stained lymph nodes, 0.8 and 1.5cm in greatest dimension. A representative section of each lymph node is submitted for frozen section evaluation and the frozen section residue is submitted in one block. The remaining tissue is entirely submitted in one block.

DESIGNATION OF SECTIONS: 5FS, 5

SUMMARY OF SECTIONS: 5FS-2, Undesignated-multiple.

SOURCE OF TISSUE: 6. Labeled #6, ""left 11 lymph node"".

GROSS DESCRIPTION: Received fresh is a 25cm in greatest dimension, gray-tan anthracotic stained lymph node which is sectioned and entirely submitted in two blocks.

DESIGNATION OF SECTIONS: 6A-6B.

SUMMARY OF SECTIONS: 6A-2, 6B-1.

SOURCE OF TISSUE: 7. Labeled #7, ""left upper lobe with chest wall"".

[page 3 of 4]
FROZEN SECTION DIAGNOSIS: 7FS - NEGATIVE BRONCHIAL MARGIN.

GROSS DESCRIPTION: Received fresh for frozen section evaluation is a 330 gram, 18.0 x 9.5 x 4.5cm left upper lobectomy of lung. It is covered by a red-purple, focally anthracotic-stained pleura having a 10.5 x 8.0 x 1.0cm portion of overlying chest wall and ribs. There is up to 0.8cm of attached bronchus. The bronchial resection margin is submitted for frozen section evaluation and the frozen section residue is submitted in one block. On sectioning through the apical segment, there is an 8.0 x 4.5 x 4.0cm firm mass, having gray-tan cut surfaces. This grossly appears to involve the overlying ribs. The remaining cut surfaces of lung are gray-tan to pink and focally anthracotic stained. There are several palpable hilar lymph nodes, 1.0cm in greatest dimension. Representative sections are submitted in fourteen blocks.

DESIGNATION OF SECTIONS: 7FS - frozen section, bronchial resection margin, 7A - vascular margins, 7B-7D - tumor with inked pleural margin, 7E-7F - random lung sections, 7G-7I - rib margins, following decalcification, 7J-7L - tumor with overlying rib, following decalcification, 7M-7N - hilar lymph nodes.

SUMMARY OF SECTIONS: 7FS-1, 7A-2, 7B-1, 7C-1, 7D-1, 7E-2, 7F-2, 7G-2, 7H-2, 7I-2, 7J-1, 7K-1, 7L-1, 7M-3, 7N-2.

SOURCE OF TISSUE: 8. Labeled #8, ""left 7 lymph node"".

GROSS DESCRIPTION: Received fresh is a 0.8cm in greatest dimension, gray-tan, firm lymph node. It is bisected and entirely submitted in one block.

DESIGNATION OF SECTIONS: Block 8.

SUMMARY OF SECTIONS: Undesignated-2.

DIAGNOSIS:

1. PORTION OF POSTERIOR LEFT FIFTH RIB:

- NO TUMOR SEEN.

2. PORTION OF POSTERIOR LEFT FOURTH RIB:

- NO TUMOR SEEN.

3. PORTION OF POSTERIOR LEFT THIRD RIB:

- NO TUMOR SEEN.

[page 4 of 4]
4. LEVEL 9 LYMPH NODE:

- ONE NEGATIVE LYMPH NODE (0/1).

5. LEVEL 5 LYMPH NODE:

- ONE NEGATIVE LYMPH NODE (0/1).

6. LEFT 11 LYMPH NODE:

- ONE NEGATIVE LYMPH NODE.

7. LEFT UPPER LOBE OF LUNG WITH CHEST WALL:

- POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 9CM, INVADING INTO THE OVERLYING RIBS (pT3).
- VASCULAR INVASION PRESENT.
- BRONCHIAL AND VASCULAR RESECTION MARGINS ARE NEGATIVE.
- SEVEN HILAR LYMPH NODES NEGATIVE FOR TUMOR (0/7).

8. LEVEL 7 LYMPH NODE:

- ONE NEGATIVE LYMPH NODE (0/1).

SYNOPTIC REPORT FOR LUNG CARCINOMA:

A NEOPLASM IS PRESENT.

LOCATION OF TUMOR: LEFT UPPER LOBE.

HISTOLOGIC CLASSIFICATION: SQUAMOUS CELL CARCINOMA, NON-KERATINIZING TYPE.

GRADE: POORLY DIFFERENTIATED, GRADE III.

MAXIMUM DIMENSION OF TUMOR: 9CM.

VENOUS INVASION: PRESENT.

INVASION THROUGH PLEURA: PRESENT.

TUMOR NECROSIS: SLIGHT.

SURGICAL MARGINS: UNINVOLVED.

NON-NEOPLASTIC LUNG SHOWS: NON-SPECIFIC INTERSTITIAL FIBROSIS.

TOTAL NODES EXAMINED: 9.

TOTAL POSITIVE NODES: 0.

STAGING: T3

N0

Source: NCI Genomic Data Commons file a4863d9d-ab1f-4054-a607-2e8822bde12b (TCGA-21-1070.32E48FF2-1C64-46C0-A1FF-EB77F4AD21B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).